Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MN, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MN-06A (Metastatic).

[page 1 of 2]
PathNet History Upload External
Client

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to: N/A

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTORICAL REQUEST DETAILS

MRN

CLINICAL NOTES

(L) axillary dissection melanoma - metastatic.

SPECIMEN INFORMATION

Lt axillary nodes - metastatic melanoma.

MACROSCOPIC DESCRIPTION

Two specimens received.

I. "Left axillary contents". A piece of fibrofatty connective tissue and skeletal muscle 195 x 110 x 65mm. The piece of skeletal muscle included is 70 x 65 x 20mm. The specimen was examined for lymph nodes.

There is a large lymph node infiltrated with tumour 60 x 40 x 30mm.

A&B. A full face section through largest node infiltrated by tumour.

C-E. 4 nodes each.

F. 3 nodes.

G. 1 node in two sections.

H-J. 1 node in four sections

K. 3 nodes

II. "?Papilloma left axilla". A fairly well defined pale tan nodule 8 x 5 x 5mm. Bisected off centre and all embedded in one block.

MICROSCOPIC REPORT

I. "Left axillary contents". There is massive replacement of the large lymph node by metastatic melanoma. No extranodal spread seen. No evidence of malignancy seen in the remaining lymph nodes.

II. "?Papilloma left axilla". Seborrhoeic keratosis.

Electronic signature

Verified by

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary c77.3
8/24/11 lw

[page 2 of 2]
Requested by: N/A

MRN/Name:

Location:

Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

SUMMARY / KEY WORDS

lymph node, axillary - malignant melanoma, metastatic
Haematopathology resection

Source: NCI Genomic Data Commons file 096856f8-f0a9-4431-8fd2-36d0efb27b0e (TCGA-EE-A2MN.6377A574-F2AA-4A18-B31B-7A368CE07A3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).